Somatic mutation profile of tumor specimen TCGA-76-4928-01B (aliquot TCGA-76-4928-01B-01D-1486-08) from TCGA case TCGA-76-4928, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 85.6 years (31,267 days).
Specimen TCGA-76-4928-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5d89ae0-ab84-426e-9359-1189db290ef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4928-10A (Blood Derived Normal), aliquot TCGA-76-4928-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8116383b-2bdc-43d8-ab24-e31790988e47

The open-access MAF lists 83 somatic variants for this specimen: 62 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 17, Frame Shift Del 3, Nonsense Mutation 2, 3'UTR 1, Intron 1, RNA 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 28/193 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs79217312, COSV68066927, COSV68069170; called by muse, mutect2, varscan2
- ADH1A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1039874400, COSV52924296; called by muse, mutect2, varscan2
- AL121899.2 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV67351173; called by muse, mutect2, varscan2
- BRWD3 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs763847217, COSV64750050; called by muse, mutect2, varscan2
- CCND2 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV54224125; called by muse, mutect2, varscan2
- CDH7 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.962); catalogued as COSV59888523; called by muse, mutect2, varscan2
- CEP97 | c.598T>G p.L200V | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59125522; called by muse, mutect2, varscan2
- CHD6 | c.4058A>C p.Q1353P | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV58558861; called by muse, mutect2, varscan2
- DENND2C | c.625C>G p.P209A | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67922389; called by muse, mutect2
- DNAH8 | c.10871A>G p.E3624G | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59458373; called by muse, mutect2, varscan2
- EIF2AK1 | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144096212; called by muse, mutect2
- EIF4A1 | c.806C>A p.T269N | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV51511272; called by muse, mutect2, varscan2
- FATE1 | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV64849076; called by muse, mutect2, varscan2
- FBN2 | c.1237T>C p.Y413H | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52523693; called by muse, mutect2, varscan2
- FBP1 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs1239199479, COSV64689504; called by muse, mutect2, varscan2
- FLG | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 61/489 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770405587, COSV64243554; called by muse, mutect2, varscan2
- FUCA1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1005744482, COSV65699323; called by muse, mutect2, varscan2
- GPR142 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759796999, COSV59518847; called by muse, mutect2, varscan2
- H3C13 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs1553755015, COSV58944506; called by muse, mutect2, varscan2
- HYDIN | c.9913G>A p.G3305S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs185616885; called by muse, mutect2, varscan2
- KCNS2 | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as COSV54639267; called by muse, mutect2, varscan2
- KLK15 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1243055731, COSV56827421; called by muse, mutect2, varscan2
- KRTAP20-2 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 18/153 reads (12%) | PolyPhen benign (0.35); catalogued as rs775016775, COSV58182540; called by muse, mutect2, varscan2
- LBP | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.362); catalogued as rs753566903, COSV54141211; called by muse, mutect2, varscan2
- LHX2 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65318669; called by muse, mutect2, varscan2
- LSMEM1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 46/263 reads (17%) | catalogued as rs773873329, COSV57196665; called by muse, mutect2, varscan2
- LY75 | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs771525072, COSV55108072; called by muse, mutect2, varscan2
- MAPK1 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.648); catalogued as COSV53187267; called by muse, mutect2, varscan2
- MRPS35 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs781130400, COSV50011709; called by muse, mutect2, varscan2
- MYH8 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753001993, COSV67967615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPBWR1 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV58696722; called by muse, mutect2, varscan2
- ORMDL3 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs879866057, COSV58345976; called by muse, mutect2, varscan2
- PCDH7 | c.2764T>C p.F922L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.758); catalogued as COSV62340410; called by muse, varscan2
- PCDHA2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV65365967; called by muse, mutect2, varscan2
- PEX14 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV63061992; called by muse, varscan2
- PIK3R6 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs368109046, COSV61003990; called by muse, mutect2, varscan2
- PKHD1 | c.11594T>A p.L3865Q | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64393192; called by muse, mutect2, varscan2
- PNPLA7 | c.2416A>G p.T806A | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV53001133; called by muse, mutect2
- PTPRF | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375234489; called by muse, mutect2, varscan2
- RPRD1B | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 16/173 reads (9%) | catalogued as COSV65033341; called by muse, mutect2
- SKIV2L | c.3008G>A p.R1003Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.348); catalogued as rs755869572, COSV61714138; called by muse, mutect2, varscan2
- SLC16A5 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs768410314, COSV100317008; called by muse, mutect2, varscan2
- SLC6A15 | c.797T>A p.I266N | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV57023897, COSV57025500; called by muse, mutect2, varscan2
- SLC9A4 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs201264205, COSV54833766; called by muse, mutect2, varscan2
- SMR3B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 66/234 reads (28%) | PolyPhen benign (0.003); catalogued as rs769338737, COSV59228723; called by muse, mutect2, varscan2
- TMPRSS13 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs923987126, COSV70626697; called by muse, mutect2, varscan2
- TMPRSS6 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60980329; called by muse, mutect2, varscan2
- TMPRSS7 | c.2412G>T p.W804C (on ENST00000452346; = p.W678C on NM_001042575.2) | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340057, COSV69981347; called by muse, mutect2, varscan2
- TRANK1 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 144/588 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV57154560; called by muse, mutect2, varscan2
- TREH | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV50622339; called by muse, mutect2, varscan2
- TRIM51 | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV55267689; called by muse, mutect2, varscan2
- TTC5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358436582, COSV51871377; called by muse, mutect2, varscan2
- UBAP2L | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55175829; called by muse, mutect2
- UNC13C | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs758672263, COSV52886684; called by muse, mutect2
- WIPI1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV100048672, COSV50930469; called by muse, mutect2, varscan2
- ASAH2 | c.1857G>A p.T619= | Splice Region (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- CPD | c.2717_2720del p.I906Kfs*37 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | called by pindel, varscan2
- ETAA1 | c.1413_1416del p.K472Yfs*7 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by pindel, varscan2
- FRG2C | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2
- GALNT7 | c.1584del p.N531Mfs*29 | Frame Shift Del (DEL) | VAF 23/171 reads (13%) | called by mutect2, pindel, varscan2
- AFM | c.1413T>A p.V471= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV56920793; called by muse, mutect2, varscan2
- ATP12A | c.474G>A p.T158= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs777069525, COSV54518563; called by muse, mutect2, varscan2
- C7orf33 | c.159C>T p.G53= | Silent (SNP) | VAF 18/274 reads (7%) | catalogued as rs549712040, COSV61023355; called by muse, mutect2
- CHD5 | c.4656C>G p.P1552= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV52418125; called by muse, mutect2
- CNTNAP1 | c.390G>A p.S130= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV52851772; called by muse, mutect2, varscan2
- GRIN2A | c.4230G>A p.S1410= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs762437402, COSV58041112; ClinVar: likely benign; called by muse, mutect2, varscan2
- ISM2 | c.660C>T p.A220= | Silent (SNP) | VAF 26/246 reads (11%) | catalogued as rs777396047, COSV53633840; called by muse, mutect2, varscan2
- KLHL8 | c.1530C>T p.Y510= | Silent (SNP) | VAF 34/254 reads (13%) | catalogued as rs749324440, COSV56747533; called by muse, mutect2, varscan2
- LAMP3 | c.861C>T p.G287= | Silent (SNP) | VAF 48/311 reads (15%) | catalogued as rs369565285; called by muse, mutect2, varscan2
- LSG1 | c.1068G>A p.Q356= | Silent (SNP) | VAF 48/360 reads (13%) | catalogued as rs1237687922, COSV54571099; called by muse, mutect2, varscan2
- LUZP2 | c.990A>G p.K330= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV61209286; called by muse, mutect2, varscan2
- MECOM | c.9C>T p.S3= (on ENST00000468789 / NM_001105078.4; = p.S191= on NM_004991.4) | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs775007213, COSV52967555; called by muse, mutect2, varscan2
- PCDHB6 | c.1686G>A p.P562= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs782507289, COSV50696238; called by muse, mutect2, varscan2
- PLXNA4 | c.5475C>T p.S1825= | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as rs114567124, COSV58137613; called by muse, mutect2, varscan2
- SPOCK1 | c.1257C>T p.A419= | Silent (SNP) | VAF 83/383 reads (22%) | catalogued as rs776151708, COSV56453389; called by muse, mutect2, varscan2
- ST8SIA5 | c.1101C>T p.R367= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1235250993, COSV59333059; called by muse, mutect2, varscan2
- TLL1 | c.1407T>C p.N469= | Silent (SNP) | VAF 38/352 reads (11%) | catalogued as COSV50296949; called by muse, mutect2, varscan2
- DCHS2 | n.3304C>T | RNA (SNP) | VAF 42/490 reads (9%) | catalogued as rs1390172512, COSV59727241; called by muse, mutect2
- NRXN1 | c.3365-109753A>G | Intron (SNP) | VAF 17/143 reads (12%) | catalogued as rs1337828997, COSV58464867; called by muse, mutect2, varscan2
- OR2T33 | c.*1T>C | 3'UTR (SNP) | VAF 55/374 reads (15%) | catalogued as COSV100531727; called by muse, mutect2, varscan2
- PVRIG | chr7:100224020 G>A | 3'Flank (SNP) | VAF 21/151 reads (14%) | catalogued as rs747142061, COSV52781726; called by muse, mutect2, varscan2
